Somatic mutation profile of tumor specimen TCGA-VT-A80G-01A (aliquot TCGA-VT-A80G-01A-11D-A36J-09) from TCGA case TCGA-VT-A80G, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 66.1 years (24,128 days).
Specimen TCGA-VT-A80G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83ad14fc-f2cf-4cb5-b3f4-c830ed6b61c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VT-A80G-11A (Solid Tissue Normal), aliquot TCGA-VT-A80G-11A-22D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30b1e0db-5b0c-4b86-8cd1-862366d2e1bd

The open-access MAF lists 71 somatic variants for this specimen: 50 protein-altering or splice-affecting, 18 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 18, Nonsense Mutation 2, RNA 2, Splice Site 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA5 | c.1435A>C p.R479= | Splice Region (SNP) | VAF 7/95 reads (7%) | catalogued as rs1253581929, COSV101201053; called by muse, mutect2
- ACVRL1 | c.667G>T p.G223C | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM040655, COSV101187810, COSV66360942; called by muse, mutect2
- AGRN | c.3286C>A p.P1096T | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV101038684, COSV65072201; called by muse, mutect2, varscan2
- ALOXE3 | c.1817C>A p.P606Q | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100559654, COSV59078397; called by muse, mutect2, varscan2
- ANKRD12 | c.3653C>T p.T1218I | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV100040981; called by muse, mutect2, varscan2
- ARHGAP30 | c.268G>A p.V90I | Missense Mutation (SNP) | VAF 60/71 reads (85%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs778067905, COSV63518562; called by muse, mutect2, varscan2
- CEP89 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.121); catalogued as COSV99993253; called by muse, mutect2, varscan2
- CILP2 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as rs777415063; called by muse, mutect2, varscan2
- COBL | c.2380A>T p.T794S | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV99471798; called by muse, mutect2, varscan2
- DHX15 | c.1491C>G p.N497K | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV100391261; called by muse, mutect2, varscan2
- ETV7 | c.74A>G p.Q25R | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs370294288; called by muse, mutect2, varscan2
- FBN1 | c.784T>A p.C262S | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100354258; called by muse, mutect2
- FLG | c.8459C>T p.T2820I | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs1465525679, COSV100911239; called by muse, mutect2, varscan2
- FLT1 | c.3836G>T p.S1279I | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs776931378, COSV99150798; called by muse, mutect2, varscan2
- FRAS1 | c.11606T>C p.I3869T | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV99349749; called by muse, mutect2, varscan2
- HERC2 | c.3971C>T p.T1324I | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.282); catalogued as rs1411667024, COSV99871926; called by muse, mutect2
- IFT27 | c.524A>T p.Y175F (on ENST00000433985 / NM_001363003.2; = p.Y174F on NM_006860.5) | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100503513; called by muse, mutect2, varscan2
- IGLV3-21 | c.191T>C p.L64P | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as rs1380881324; called by muse, mutect2
- INO80C | c.490A>G p.I164V | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV100577211; called by muse, mutect2, varscan2
- KRT26 | c.341A>C p.K114T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59413495; called by muse, mutect2, varscan2
- MAB21L2 | c.215C>A p.T72N | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100461999; called by muse, mutect2, varscan2
- MACF1 | c.2552G>A p.R851K | Missense Mutation (SNP) | VAF 16/83 reads (19%) | catalogued as COSV100483377; called by muse, mutect2, varscan2
- MAGEA4 | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 38/46 reads (83%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as COSV99367392; called by muse, mutect2, varscan2
- MAN1C1 | c.982G>C p.G328R | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99848008; called by muse, mutect2, varscan2
- MDM1 | c.1609G>T p.G537C | Missense Mutation (SNP) | VAF 46/78 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100291720; called by muse, mutect2, varscan2
- MLKL | c.1265A>C p.K422T | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100087244, COSV58205761; called by muse, mutect2
- MUC16 | c.11738A>C p.N3913T | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.017); catalogued as COSV101198933; called by muse, mutect2
- MYH1 | c.2493G>T p.W831C | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV99875316; called by muse, mutect2
- MYH9 | c.50T>C p.I17T | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV99338229; called by muse, mutect2
- OR56B1 | c.96G>C p.W32C | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100402569, COSV57722537; called by muse, mutect2, varscan2
- PCLO | c.11090T>A p.F3697Y | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV100429347; called by muse, mutect2, varscan2
- PON1 | c.606G>C p.W202C | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99732106; called by muse, mutect2, varscan2
- PRAME | c.872A>T p.Q291L | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101287040; called by muse, mutect2
- RIMS2 | c.230A>C p.E77A | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.732); catalogued as rs1344508136, COSV101344374; called by muse, mutect2, varscan2
- RIOK1 | c.440A>G p.Y147C | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99344651; called by muse, mutect2, varscan2
- SAP130 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.981); catalogued as COSV99384372; called by muse, mutect2, varscan2
- SEC14L5 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 37/44 reads (84%) | SIFT tolerated (0.38); PolyPhen benign (0.297); catalogued as COSV99228696; called by muse, mutect2, varscan2
- TAF1C | c.2251A>G p.K751E | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100499476; called by muse, mutect2, varscan2
- TENM3 | c.7466T>C p.F2489S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101304967; called by muse, mutect2
- TKTL1 | c.349A>T p.S117C | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99473821; called by muse, mutect2, varscan2
- TMCO3 | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 32/36 reads (89%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as rs932009879, COSV100952318, COSV64807657; called by muse, mutect2, varscan2
- TMEM132B | c.1472G>T p.S491I | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV100168978, COSV54772245; called by muse, mutect2, varscan2
- TUBB6 | c.251T>C p.L84P | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as COSV100480992; called by muse, mutect2
- VWCE | c.267G>C p.Q89H | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100075682; called by muse, mutect2, varscan2
- WDR64 | c.1483G>T p.E495* | Nonsense Mutation (SNP) | VAF 57/68 reads (84%) | catalogued as COSV100843703; called by muse, mutect2, varscan2
- ZNF488 | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 18/55 reads (33%) | catalogued as rs782272737; called by muse, mutect2, varscan2
- ZNF615 | c.659T>C p.I220T | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100943741; called by muse, mutect2, varscan2
- ZNF831 | c.1369C>T p.R457C | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100925897; called by muse, varscan2
- ANXA1 | c.476-12_503del p.X159_splice | Splice Site (DEL) | VAF 34/117 reads (29%) | called by mutect2, pindel
- IGHV1OR21-1 | c.260T>C p.V87A | Missense Mutation (SNP) | VAF 54/255 reads (21%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- AC098582.1 | c.613C>T p.L205= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as rs1467318619, COSV99985409, COSV99985729; called by muse, mutect2, varscan2
- ADSL | c.1422C>T p.S474= | Silent (SNP) | VAF 29/128 reads (23%) | catalogued as rs748593655, COSV50651472; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC144A | c.1740A>G p.E580= | Silent (SNP) | VAF 19/135 reads (14%) | catalogued as COSV100138443; called by muse, mutect2, varscan2
- ENTHD1 | c.516T>G p.T172= | Silent (SNP) | VAF 13/182 reads (7%) | catalogued as COSV100288585; called by muse, mutect2
- GBGT1 | c.873C>T p.I291= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV100923763; called by muse, mutect2, varscan2
- IGLON5 | c.315C>T p.G105= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as rs773241114, COSV99570532; called by muse, mutect2, varscan2
- ITGA10 | c.267C>A p.G89= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV100994790; called by muse, mutect2, varscan2
- KIAA1841 | c.2010G>A p.K670= | Silent (SNP) | VAF 8/150 reads (5%) | catalogued as COSV99693480; called by muse, mutect2
- KIF16B | c.2646C>T p.V882= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100734006; called by muse, mutect2
- LRP2 | c.7806C>G p.G2602= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99787222; called by muse, mutect2
- MPPED1 | c.954C>T p.I318= | Silent (SNP) | VAF 49/199 reads (25%) | catalogued as rs763555881, COSV101342217, COSV68839072; called by muse, mutect2, varscan2
- PDE6A | c.2319A>G p.Q773= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as COSV99678029; called by muse, mutect2, varscan2
- RGS18 | c.84A>T p.S28= | Silent (SNP) | VAF 20/152 reads (13%) | catalogued as rs747605141, COSV100817701; called by muse, mutect2, varscan2
- SEC14L5 | c.927G>C p.L309= | Silent (SNP) | VAF 22/24 reads (92%) | catalogued as COSV99228692; called by muse, mutect2, varscan2
- SPATA31D1 | c.2484T>C p.N828= | Silent (SNP) | VAF 82/154 reads (53%) | catalogued as COSV100782614; called by muse, mutect2, varscan2
- UBA6 | c.1176A>G p.A392= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as COSV100451614; called by muse, mutect2, varscan2
- ZSCAN4 | c.381A>T p.I127= | Silent (SNP) | VAF 33/57 reads (58%) | catalogued as COSV100552428; called by muse, mutect2, varscan2
- ZSCAN5B | c.1386C>T p.S462= | Silent (SNP) | VAF 37/102 reads (36%) | catalogued as rs367702594; called by muse, mutect2, varscan2
- C9orf16 | c.-2C>G | 5'UTR (SNP) | VAF 12/31 reads (39%) | catalogued as COSV100882850; called by muse, mutect2, varscan2
- MIR520A | n.16T>C | RNA (SNP) | VAF 48/158 reads (30%) | catalogued as rs1172516897; called by muse, mutect2, varscan2
- OR2U1P | n.743T>C | RNA (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
